Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAFF, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAFF-01A (Primary Tumor).

Department of Pathology

ICD-O-3
Seminoma NOS 9061/3
Site (L) Testis NOS C62.9
9/13/14

Concerning

Summary pathology report

Left orchidectomy; seminoma; diameter 1.5 cm; tumor confined to testis in available slides; no angio-invasion; invasion in rete testis present.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file fd0ce554-d2bf-4984-bd92-f918d788d94e (TCGA-2G-AAFF-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).